Somatic mutation profile of tumor specimen ALCH-B363-TTP1-A (aliquot ALCH-B363-TTP1-A-2-0-D-A780-36) from ALCHEMIST case ALCH-B363, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.3 years (20,202 days).
Specimen ALCH-B363-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89c8511b-7527-42a4-a0d0-db9186d9bec4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B363-NB1-A (Blood Derived Normal), aliquot ALCH-B363-NB1-A-1-0-D-A780-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/304a9ce9-e4e1-49ea-a76d-d1c31d085ba0

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 16/286 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- GAPDH | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.04); catalogued as COSV57520441, COSV57521500; called by mutect2, varscan2
- KRT37 | c.1177G>A p.V393M | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as rs141724873; called by muse, mutect2
- NEU3 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53639080; called by muse, mutect2
- NTRK3 | c.715C>A p.P239T | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV58137851; called by muse, mutect2
- TG | c.7111C>T p.R2371* | Nonsense Mutation (SNP) | VAF 11/138 reads (8%) | catalogued as rs1410846026, COSV55085851; called by muse, mutect2
- BICC1 | c.1543C>A p.P515T | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- DOLK | c.1181T>C p.L394P | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.242); called by mutect2, varscan2
- KLF8 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- NTM | c.8T>A p.V3D | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.361); called by muse, varscan2
- PIEZO2 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 7/168 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by muse, mutect2
- SPATA31D3 | c.252G>C p.K84N | Missense Mutation (SNP) | VAF 3/284 reads (1%) | SIFT deleterious (0.05); PolyPhen benign (0.097); called by muse, mutect2
- ZNF761 | c.1592T>G p.F531C | Missense Mutation (SNP) | VAF 8/213 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR11A1 | c.822C>T p.V274= | Silent (SNP) | VAF 24/252 reads (10%) | called by muse, mutect2
- TOM1 | c.-9G>A | 5'UTR (SNP) | VAF 8/105 reads (8%) | called by muse, mutect2
